Surgical pathology report (de-identified scan), TCGA case TCGA-A2-A0YM, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Walter Reed, specimen TCGA-A2-A0YM-01A (Primary Tumor).

[page 1 of 4]
ICD-0-3

Carcinoma, infiltrating duct, Nos 8500/3
Site: breast, Nos C50.9 - 1/27/11 hr

SURGICAL REPORT

Name

Sex: F

DOB

Location:

Doctor:

Pathology Number

Date Collected:

Date Received:

M.R. Number:

Account Number:

PRE-OPERATIVE DIAGNOSIS

LEFT BREAST CANCER

POST-OPERATIVE DIAGNOSIS

LEFT BREAST CANCER

PROCEDURE

LEFT BREAST LUMPECTOMY, LEFT AXILLARY SENTINEL MAPPING, F.S.

TISSUES

- A. BREAST EXCISION, NEEDLE LOC, SIMPLE, MARGINS, ETC. - LEFT BREAST LUMP
- B. MARGINS - ADDITIONAL ANTERIOR MARGIN
- C. MARGINS - ADDITIONAL SUPERIOR MARGIN
- D. LYMPH NODE (S) - SENTINEL LYMPH NODE #1 **FS**
- E. LYMPH NODE (S) - SENTINEL LYMPH NODE #2 **FS**
- F. LYMPH NODE (S) - SENTINEL LYMPH NODE #3 **FS**
- G. LYMPH NODE (S) - SENTINEL LYMPH NODE #4 **FS**
- H. LYMPH NODE (S) - ADDITIONAL NON-SENTINEL NODE **FS**

FS DIAGNOSIS

- A. LEFT BREAST LUMP "GROSS MARGINS" -
BREAST TISSUE WITH TUMOR (2.4 X 2.2 X 2.2 CM.) EXTENDING WITHIN 0.2 CM.
OF NEAREST SUPERIOR SURGICAL MARGIN AND 0.3 CM. OF ANTERIOR SURGICAL
MARGIN.

ALL DESIGNATED SURGICAL MARGINS ARE FREE OF TUMOR (GROSS).

- D. SENTINEL LYMPH NODE #1, F.S. -
LYMPH NODE, NEGATIVE FOR MALIGNANCY.
- E. SENTINEL LYMPH NODE #2, F.S. -
LYMPH NODE, NEGATIVE FOR MALIGNANCY.
- F. SENTINEL LYMPH NODE #3, F.S. -
LYMPH NODE, NEGATIVE FOR MALIGNANCY.
- G. SENTINEL LYMPH NODE #4, F.S. -
LYMPH NODE, NEGATIVE FOR MALIGNANCY.
- H. SENTINEL LYMPH NODE #5, F.S. -
LYMPH NODE, NEGATIVE FOR MALIGNANCY.

(Reported to surgeon:

Patient Name:

Pathology Number:

SURGICAL REPORT

RECEIVED

Page 1 of 4

[page 2 of 4]
Patient Name:

Pathology Number:

Diagnosed by:

FINAL DIAGNOSIS

- A. LEFT BREAST LUMP -
INFILTRATIVE DUCT CARCINOMA (2.4 CM.).
BLOOM-RICHARDSON GRADING:
GRADE III OF III (MINIMAL TUBULE FORMATIONS, HIGH NUCLEAR GRADE
AND HIGH MITOTIC INDEX).
DCIS:
NONE IDENTIFIED.
TUMORAL NECROSIS/CALCIFICATION:
NECROSIS ONLY.
LOBULAR CANCERIZATION:
PRESENT, FOCAL.
SURGICAL MARGINS:
UNINVOLVED, SUPERIOR MARGIN IS THE CLOSEST AND IS 0.2 CM. FROM
THE TUMOR.**
- B. ADDITIONAL ANTERIOR MARGIN -
BENIGN BREAST TISSUE, THE NEW REVISED ANTERIOR MARGIN IS 0.9 CM. (0.3
+ 0.6 CM.).**
- C. ADDITIONAL SUPERIOR MARGIN -
BENIGN BREAST TISSUE, THE NEW REVISED SUPERIOR MARGIN IS 0.8 CM.
(0.2 + 0.6 CM.).**
- D. SENTINEL LYMPH NODE #1 -
ONE BENIGN REACTIVE LYMPH NODE (0/1).**
- E. SENTINEL LYMPH NODE #2 -
ONE BENIGN REACTIVE LYMPH NODE (0/1).**
- F. SENTINEL LYMPH NODE #3 -
ONE BENIGN REACTIVE LYMPH NODE (0/1).**
- G. SENTINEL LYMPH NODE #4 -
ONE BENIGN REACTIVE LYMPH NODE (0/1).**
- H. ADDITIONAL NON-SENTINEL LYMPH NODE -
ONE BENIGN REACTIVE LYMPH NODE.**

PTNM CLASSIFICATION: T2, N0, MX, STAGE IIA.

Diagnosed by:

Reviewed and electronically signed out by:

COMMENT

The ER, PR, and Her-2/neu have been performed on previous surgical
discussed with Dr. by Dr.

This case is

COMMENT2

Patient Name:

Pathology Number:

SURGICAL REPORT

Page 2 of 4

[page 3 of 4]
Lymph nodes in parts D, E, F, G and H are negative for malignancy by Cytokeratin (AE1/AE3) staining.

GROSS DESCRIPTION

The specimen is received in eight separate containers labeled through H.

Initiated A

- A. The container is received fresh unfixed labeled "left breast lump for gross margin". The specimen consists of a 20 gm. ovoid mass of apparent fatty and fibrous encased tissue which is 4.1 x 3.3 x 2.5 cm. in greatest overall dimension. There is a single short suture indicating anterior margin inked with yellow dye, posterior/deep margin is inked black. There are two short sutures indicating superior margin inked with orange dye, inferior is inked red. There is a single long suture indicating lateral margin inked with blue dye, medial is inked green. Sectioning reveals a well-circumscribed tumor mass which is 2.4 x 2.2 x 2.2 cm. in greatest overall dimension and consists of a pink-tan firm with scattered cystic spaces filled with amber-colored fluid. The tumor mass grossly appears to be 0.3 cm. from the anterior, 0.5 cm. from the posterior/deep, 0.2 cm. from the superior, 0.4 cm. from the inferior, 0.6 cm. from the lateral, 0.6 cm. from the medial. The specimen is submitted in ten blocks.

Key Note Block Summary: 1—anterior, 2—posterior/deep, 3—superior, 4—inferior, 5—medial, 6—lateral, 7 through 10—remaining.

- B. The container is received fresh unfixed labeled "additional anterior margin – suture on new anterior margin". The specimen consists of a 2 gm. ovoid mass of apparent fatty tissue which is 3.5 x 2 x 0.6 cm. in greatest overall dimension. There is an attached suture indicating new anterior margin inked orange. Serial sectioning reveals fatty tissue and a scant amount of pink-tan firm tissue. The entire specimen is submitted in two blocks.
- C. The container is received fresh unfixed labeled "additional superior margin – suture on new superior margin". The specimen consists of a 3 gm. ovoid mass of apparent fatty tissue which is 2.5 x 2.5 x 0.6 cm. in greatest overall dimension. The attached suture indicates new superior margin inked with yellow dye. Serial sectioning reveals fatty tissue. The entire specimen is submitted in two blocks.
- D. The container is received fresh unfixed labeled "sentinel lymph node #1 for frozen section". The specimen consists of an ovoid nodule of tan-gray firm rubbery tissue with attached fatty material measuring 0.6 x 0.6 x 0.4 cm. Touch prep and frozen section are obtained by Dr. The entire specimen including frozen section is submitted in two blocks.
- E. The container is received fresh unfixed labeled "sentinel lymph node #2 for frozen section". The specimen consists of an ovoid nodule of tan-gray firm rubbery tissue with attached fatty material 0.3 x 0.3 x 0.2 cm. Touch prep and frozen section are obtained by Dr. The specimen is bisected and the entire specimen including frozen section is submitted in two blocks.
- F. The container is received fresh unfixed labeled "sentinel lymph node #3". The specimen consists of an ovoid nodule of tan-gray firm rubbery tissue with attached fatty material 0.3 x 0.3 x 0.3 cm. Frozen section and touch prep are obtained by Dr. The specimen is bisected and the entire specimen including frozen section is submitted in two blocks.
- G. The container is received fresh unfixed labeled "sentinel lymph node #4 for frozen section". The specimen consists of an ovoid nodule of tan-gray firm rubbery tissue with fatty material 0.6 x 0.3 x 0.3 cm. Frozen section and touch prep are obtained by Dr. The specimen is bisected. The entire specimen including frozen section is submitted in two blocks.

Patient Name:

Pathology Number

[page 4 of 4]
Patient Name:

Pathology Number:

- H. The container is received fresh unfixed labeled "additional non-sentinel node for frozen section". The specimen consists of an ovoid nodule of tan-gray firm rubbery tissue with attached fatty material 0.3 x 0.2 x 0.2 cm. Frozen section and touch prep are obtained by Dr. The specimen is bisected. The entire specimen including frozen section is submitted in two blocks.

MICROSCOPIC EXAM

MICROSCOPIC EXAMINATION CONDUCTED BY PATHOLOGIST CONFIRMS FINAL DIAGNOSIS.

SPECIAL STAINS PERFORMED: Cytokeratin (AE1/AE3) (specimens D, E, F, G, H)

HIFAA Discrepancy		

Patient Name:

Pathology Number:

SURGICAL REPORT

Page 4 of 4

Source: NCI Genomic Data Commons file f3172803-f446-4935-a742-e72e0fcf7899 (TCGA-A2-A0YM.E1D8F2CB-25F1-49E0-92D3-132DCA8FD533.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).